Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8373, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8373-01A (Primary Tumor).

[page 1 of 3]
	Case ID	Gross Description	Microscopic Description
		Stomach segment with a plate-like tumour, of 6.5 cm in greatest dimension, whole wall invasion; fatty tissue lymph nodes are enlarged, soft; omentum - hyperemia.	Adenocarcinoma of the stomach, G2; with perigastric fat invasion. Fifteen lymph nodes were examined, two demonstrated metastases, with extensive necrosis. Omentum - hyperemia.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Fundus Tumor size: 6.5 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Moderately differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 2/15 positive for metastasis (Greater and lesser omentum 2/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 637a9f3c-b849-4a01-96bd-6289bddf0df7 (TCGA-BR-8373.87C67D3F-2F68-48ED-A0E7-75B522EE92D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).